Somatic mutation profile of tumor specimen TCGA-EJ-A6RA-01A (aliquot TCGA-EJ-A6RA-01A-11D-A33T-08) from TCGA case TCGA-EJ-A6RA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.3 years (25,679 days).
Specimen TCGA-EJ-A6RA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db1765c0-fede-42a1-a00f-d8ff4023bd46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A6RA-10A (Blood Derived Normal), aliquot TCGA-EJ-A6RA-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecd7f19c-ab80-4b94-bd00-48d440da0d28

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ1B | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100289871; called by muse, mutect2, varscan2
- FMO4 | c.657G>C p.W219C | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100882080; called by muse, mutect2
- KIF21A | c.139A>C p.K47Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100735515; called by muse, mutect2
- LRP1B | c.4567C>T p.R1523C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773682116, COSV67237878, COSV67248772; called by muse, mutect2
- TFCP2L1 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99748363; called by muse, mutect2
- WDR76 | c.1433G>A p.R478K | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99776487; called by muse, mutect2
- KIAA1109 | c.8904A>G p.P2968= | Silent (SNP) | VAF 6/107 reads (6%) | catalogued as rs1426265714, COSV99166405; called by muse, mutect2
- LYN | c.231C>A p.I77= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV101571242; called by muse, mutect2
- SNTN | c.36T>C p.S12= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100662638; called by muse, mutect2
